Somatic mutation profile of tumor specimen TARGET-10-PAPERU-09A (aliquot TARGET-10-PAPERU-09A-01D) from TARGET case TARGET-10-PAPERU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,133 days).
Specimen TARGET-10-PAPERU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cfa7439-5df4-495e-bcb7-db6e5be323de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPERU-14A (Bone Marrow Normal), aliquot TARGET-10-PAPERU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57158086-0b7d-4875-bd69-9def6ba9cd74

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Intron 2, Nonsense Mutation 1, Frame Shift Del 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCAM | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs766822712, COSV54301216; called by muse, mutect2, varscan2
- GRM3 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601607, COSV64468584; called by muse, mutect2, varscan2
- KIAA1549 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs374288943; called by mutect2, varscan2
- NDUFAF7 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1220101288, COSV50017083; called by muse, mutect2
- POLM | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs145947306; called by muse, mutect2, varscan2
- RIMS1 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as rs771849493, COSV53467710; called by muse, mutect2, varscan2
- SLC25A31 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as rs755877465; called by muse, mutect2, varscan2
- SOX2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM030717, COSV57620993; called by muse, mutect2, varscan2
- BHLHE41 | c.508G>C p.A170P | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- BUB1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CEP170 | c.4484A>G p.D1495G | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DPYSL4 | c.730_755delinsC p.K244Pfs*4 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by pindel, varscan2*
- DUOXA2 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGOHB | c.11_12insCCC p.A4_S5insP | In Frame Ins (INS) | VAF 46/105 reads (44%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2
- RRBP1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TEK | c.1754A>G p.K585R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- WDR59 | c.695C>G p.P232R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZDBF2 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EIF5B | c.2664C>T p.I888= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- L3MBTL4 | c.544A>C p.R182= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- PLCH2 | c.1017G>A p.S339= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs143425245; called by muse, mutect2, varscan2
- QTRT1 | c.540C>T p.R180= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- SUSD4 | c.924G>A p.T308= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs747238890, COSV59555850; called by muse, mutect2, varscan2
- TNPO1 | c.411C>T p.L137= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- CPSF4 | c.404-108T>C | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- DLG2 | c.205-21958C>A | Intron (SNP) | VAF 42/108 reads (39%) | called by muse, mutect2, varscan2
- EPB41L3 | c.-43G>A | 5'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs956926261; called by muse, mutect2
